Surgical pathology report (de-identified scan), TCGA case TCGA-14-1825, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-1825-01A (Primary Tumor).

[page 1 of 2]
AP Report

* Final Report *

Document Type: AP Report
Document Date:
Document Status: Auth (Verified)
Document Title: AP REPORT
Encounter info:

TCGA-14-1825

* Final Report *

AP REPORT

Patient:

Accession Number:

Patient Number:

Date Collected:

Financial Number:

Date Received:

Room/Bed:

PT:

Admitting Physician:

Ordering Physician:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, RIGHT PARIETAL OCCIPITAL LESION, RESECTION:
-GLIOBLASTOMA (WHO GRADE IV).

2. BRAIN, RIGHT PARIETAL OCCIPITAL LESION, RESECTION:
-GLIOBLASTOMA (WHO GRADE IV).

SPECIMEN:

1. Right parietal occipital lesion.
2. Right parietal occipital lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Malignant neoplasm, occipital lobe. Right craniotomy for tumor removal.

GROSS DESCRIPTION:

The specimen is received in two parts, each labeled with the patient's name

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 2]
AP Report

* Final Report *

and medical record number.

TCGA-14-1825

Specimen #1 is received fresh for intraoperative consultation and labeled as "right parietal occipital lesion." The specimen consists of three fragments of soft cream colored tissue measuring 0.4 x 0.3 x 0.3 cm in aggregate. A portion of the specimen is submitted for intraoperative frozen section diagnosis and touch prep, and the remainder of the cryoblock is transferred to cassette "FS1A." The remainder of the specimen is submitted entirely in cassette "1B."

Specimen #2 is received in formalin and labeled as "right parietal occipital lesion." The specimen consists of multiple fragments of soft cream to tan colored tissue measuring 1.9 x 1.6 x 0.5 cm in aggregate. Representative sections are submitted in cassettes "2A" and "2B."

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: BRAIN, PARIETAL OCCIPITAL LESION, BIOPSY (FROZEN SECTION, TOUCH PREPARATION): GLIOBLASTOMA.

Pathologist:

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

Fellow:

The pathologist has reviewed and interpreted the case with the resident/fellow.

Medical Records

Page 1 (End of Report)

Printed by:
Printed on:

Page 2 of 3
(Continued)

Source: NCI Genomic Data Commons file 9f80154a-3521-4448-aad3-1f0fba1bd1c9 (TCGA-14-1825.67478A3B-8B41-4571-BC63-36780F0D19E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).